TCGA case TCGA-WD-A7RX — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4290b3b3-94f6-43e4-8309-430dd973ae2d

Demographics
Sex at birth: female; Race: white; Ethnicity: hispanic or latino; Country of residence at enrollment: United States; Age at index: 71 years; Vital status: Dead; Days to death: 21 days.

Diagnoses (1)
1. Cholangiocarcinoma: ICD-O-3 morphology code: 8160/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 71.2 years (26,006 days); Year of diagnosis: 2013; AJCC staging edition: 7th; AJCC pathologic T: T2b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage II; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: RX; Ishak fibrosis score: 3,4 - Fibrous Septa.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 21 days; Disease response: Tumor Free.
- ECOG performance status: 0.

Molecular and laboratory tests
- CA19-9: 34 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 37.
- Albumin 3.7 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 4.8].
- Alpha Fetoprotein 2.6 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 8.1].
- Prothrombin Time 12.2 Seconds [Blood test normal range lower: 10.4; Blood test normal range upper: 13.1].
- Platelets 156 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 400].
- Total Bilirubin 0.6 mg/dL [Blood test normal range lower: 0.3; Blood test normal range upper: 1.2].
- Creatinine 0.9 mg/dL [Blood test normal range lower: 0.4; Blood test normal range upper: 1].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 51 kg; Height: 147 cm; BMI: 23.6.
- Timepoint category: Prior to Diagnosis; Risk factors: Liver Cirrhosis (Liver Disease) / Diabetes, NOS / Tobacco, Smoking.

Family history
- Relatives with cancer history count: 1.
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Multiple Myeloma.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-WD-A7RX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 250 mg.
  Slide TCGA-WD-A7RX-01A-01-TSA: Section location: Top; Percent tumor cells: 56; Percent tumor nuclei: 80; Percent normal cells: 4; Percent necrosis: 1; Percent stromal cells: 39; Percent lymphocyte infiltration: 15; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 1.
- Sample TCGA-WD-A7RX-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-WD-A7RX-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; History neoadjuvant treatment: No; Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, intrahepatic; Surgical procedure other: Right Hepatectomy; Ishak fibrosis score: 3,4 - Fibrous Speta.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 21 days; disease-specific survival: no event (censored), 21 days; progression-free interval: no event (censored), 21 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-WD-A7RX-01A-12D-A416-01): tumor purity 0.51, ploidy 1.75, whole-genome doublings 0.
